Somatic mutation profile of tumor specimen TCGA-QR-A70A-01A (aliquot TCGA-QR-A70A-01A-11D-A35D-08) from TCGA case TCGA-QR-A70A, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 54.1 years (19,755 days).
Specimen TCGA-QR-A70A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0dd47887-238d-4538-b00a-d612660f2f48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A70A-10A (Blood Derived Normal), aliquot TCGA-QR-A70A-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9c97ba5-b2fd-4576-92c5-b960ba760d6d

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG7 | c.2339C>G p.P780R | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV56293266; called by muse, mutect2, varscan2
- FGFR2 | c.2068G>A p.G690R | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1311258996, COSV100336630, COSV60659184; called by muse, mutect2, varscan2
- HUWE1 | c.11338C>T p.R3780C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); catalogued as COSV53335006; called by muse, mutect2, varscan2
- SLITRK4 | c.946G>T p.V316F | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.18); catalogued as rs142699085, COSV100567349; called by muse, mutect2, varscan2
- AADACL4 | c.995T>A p.V332D | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ARNT2 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCMF1 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.095); called by muse, mutect2
- PQBP1 | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCC4 | c.1974G>A p.S658= | Silent (SNP) | VAF 13/158 reads (8%) | catalogued as rs1246815789; called by muse, mutect2
- ADAM11 | c.1593C>T p.D531= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as rs1185891749, COSV99567467; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6135T>G p.S2045= | Silent (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- DTX4 | c.1317A>G p.R439= | Silent (SNP) | VAF 26/156 reads (17%) | called by muse, mutect2, varscan2
- RNF8 | c.219A>G p.Q73= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs184803752; called by muse, mutect2, varscan2
